FM case AD6064 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Anus and anal canal.
https://portal.gdc.cancer.gov/cases/d94b1262-c9dd-465a-843e-275828560a32

Female, 47.8 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the anus; primary biopsied or resected from the anal canal. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
